Somatic mutation profile of tumor specimen MBCProject_0799_T1_WES (aliquot MBCProject_0799_T1_WES_1) from CMI case MBCProject_0799, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 56.5 years (20,631 days).
Specimen MBCProject_0799_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node(s) Axilla; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) df01e575-8fcd-4512-91de-d14be7baf767.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_0799_SALIVA (Saliva), aliquot MBCProject_0799_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fdf1c8c3-d64a-4467-b450-658e1274eef2

The open-access MAF lists 47 somatic variants for this specimen: 31 protein-altering or splice-affecting, 11 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 11, Nonsense Mutation 2, 3'UTR 2, Frame Shift Del 1, Intron 1, Frame Shift Ins 1, Splice Region 1, 5'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 20/135 reads (15%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 85/159 reads (53%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ATP2B3 | c.594C>G p.I198M | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.745); catalogued as rs2269409; called by muse, mutect2, varscan2
- CBFB | c.165C>A p.I55= | Splice Region (SNP) | VAF 57/96 reads (59%) | catalogued as rs780403146; called by muse, mutect2, varscan2
- CTAG2 | c.184C>T p.R62W | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.898); catalogued as rs1158536572, COSV55994412; called by muse, mutect2, varscan2
- ESX1 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 30/158 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.303); catalogued as COSV101006430; called by muse, mutect2, varscan2
- FAT4 | c.10592C>T p.T3531I | Missense Mutation (SNP) | VAF 11/325 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); catalogued as COSV58695186; called by muse, mutect2
- KCNC2 | c.356G>A p.R119H | Missense Mutation (SNP) | VAF 54/239 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54371719; called by muse, mutect2, varscan2
- KCNQ2 | c.2120C>T p.A707V (on ENST00000359125 / NM_172107.4; = p.A679V on NM_004518.6) | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs753033741; called by muse, mutect2, varscan2
- KCP | c.3982C>T p.R1328* (on ENST00000620378; = p.R1452* on NM_001366122.1) | Nonsense Mutation (SNP) | VAF 13/45 reads (29%) | catalogued as rs1469870148; called by muse, varscan2
- MAP2 | c.728C>A p.P243Q | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.855); catalogued as rs756870042; called by muse, mutect2, varscan2
- MBTPS1 | c.61C>A p.L21M | Missense Mutation (SNP) | VAF 43/146 reads (29%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.062); catalogued as COSV58572584; called by muse, mutect2, varscan2
- PROS1 | c.1660G>T p.V554F | Missense Mutation (SNP) | VAF 36/133 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.875); catalogued as COSV101260915; called by muse, mutect2, varscan2
- SEMA3C | c.1229C>A p.S410Y | Missense Mutation (SNP) | VAF 38/186 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.192); catalogued as rs776985479; called by muse, mutect2, varscan2
- SIRPG | c.722C>G p.T241S | Missense Mutation (SNP) | VAF 24/226 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs1262888704; called by muse, mutect2
- ARHGAP31 | c.2535C>A p.D845E | Missense Mutation (SNP) | VAF 103/537 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARID1A | c.713_720del p.T238Ifs*159 | Frame Shift Del (DEL) | VAF 10/30 reads (33%) | called by mutect2, pindel, varscan2
- CBFB | c.164T>A p.I55N | Missense Mutation (SNP) | VAF 57/96 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); called by muse, mutect2, varscan2
- CDAN1 | c.452G>A p.R151Q | Missense Mutation (SNP) | VAF 46/102 reads (45%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- CHRND | c.1159G>A p.A387T | Missense Mutation (SNP) | VAF 38/170 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FCGBP | c.4577C>T p.T1526I | Missense Mutation (SNP) | VAF 11/251 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); called by muse, mutect2
- GLI3 | c.877A>G p.T293A | Missense Mutation (SNP) | VAF 63/546 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MAP3K1 | c.2641C>T p.Q881* | Nonsense Mutation (SNP) | VAF 46/71 reads (65%) | called by muse, mutect2, varscan2
- NRXN2 | c.4616G>T p.R1539M | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.345); called by muse, mutect2
- PITX3 | c.281dup p.I95Dfs*167 | Frame Shift Ins (INS) | VAF 22/130 reads (17%) | called by mutect2, pindel, varscan2
- SLC35E1 | c.390C>G p.I130M | Missense Mutation (SNP) | VAF 58/218 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- SLC35G2 | c.980G>A p.C327Y | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.996); called by muse, mutect2
- SLC35G2 | c.982T>G p.S328A | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.982); called by muse, mutect2
- TP53BP2 | c.106G>A p.D36N | Missense Mutation (SNP) | VAF 40/423 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); called by muse, mutect2
- TTN | c.46260G>T p.K15420N (on ENST00000591111; = p.K7996N on NM_003319.4) | Missense Mutation (SNP) | VAF 40/283 reads (14%) | PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TTN | c.42343T>C p.Y14115H (on ENST00000591111; = p.Y6691H on NM_003319.4) | Missense Mutation (SNP) | VAF 47/217 reads (22%) | PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- GLI2 | c.2946G>A p.P982= (on ENST00000361492 / NM_001374353.1; = p.P999= on NM_005270.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 31/252 reads (12%) | catalogued as rs1305631445, COSV58051954; called by muse, mutect2, varscan2
- HGSNAT | c.549G>C p.L183= | Silent (SNP) | VAF 28/67 reads (42%) | called by muse, mutect2, varscan2
- HMCN2 | c.4704C>T p.D1568= | Silent (SNP) | VAF 39/88 reads (44%) | catalogued as rs1040501756; called by muse, mutect2, varscan2
- ITGA9 | c.1392G>A p.T464= | Silent (SNP) | VAF 45/222 reads (20%) | catalogued as rs770099797; called by muse, mutect2, varscan2
- KANK2 | c.1425C>G p.P475= (on ENST00000586659 / NM_001379562.1; = p.P483= on NM_015493.7 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 15/78 reads (19%) | called by muse, mutect2, varscan2
- KDR | c.1743C>T p.L581= | Silent (SNP) | VAF 23/116 reads (20%) | called by muse, mutect2, varscan2
- MYO5C | c.1620A>G p.R540= | Silent (SNP) | VAF 23/153 reads (15%) | called by muse, mutect2, varscan2
- MYRIP | c.1995G>A p.G665= | Silent (SNP) | VAF 79/184 reads (43%) | called by muse, mutect2, varscan2
- SDK1 | c.6498G>A p.A2166= | Silent (SNP) | VAF 48/245 reads (20%) | catalogued as rs778396777, COSV67360806; called by muse, mutect2, varscan2
- SSC5D | c.3927G>A p.T1309= | Silent (SNP) | VAF 9/60 reads (15%) | catalogued as rs749076657; called by muse, mutect2, varscan2
- VWC2 | c.564G>A p.A188= | Silent (SNP) | VAF 37/212 reads (17%) | catalogued as rs1387492364, COSV100514149; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.1046+2947G>A | Intron (SNP) | VAF 94/255 reads (37%) | catalogued as rs747921046, COSV58442745; called by muse, mutect2, varscan2
- EIF2AK1 | c.*784_*787del | 3'UTR (DEL) | VAF 32/190 reads (17%) | called by mutect2, pindel
- FAM20A | c.*250G>A | 3'UTR (SNP) | VAF 12/83 reads (14%) | catalogued as rs944107686; called by muse, mutect2
- RBM3 | chrX:48574491 G>A | 5'Flank (SNP) | VAF 6/43 reads (14%) | called by muse, mutect2
- RP2 | c.-13G>A | 5'UTR (SNP) | VAF 46/261 reads (18%) | called by muse, mutect2, varscan2
